TCGA case TCGA-NH-A6GB — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Candler. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e3b0ee77-c419-4b2b-833f-90a221415489

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.4; Tissue or organ of origin: Transverse colon; Site of resection or biopsy: Transverse colon; Classification of tumor: primary; Age at diagnosis: 71.5 years (26,100 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N2b; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIC; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 476 days (1.3 years).
   Pathology details: Circumferential resection margin: 25; Consistent pathology review: Yes; Lymph nodes positive: 7; Lymph nodes tested: 13; Lymphatic invasion present: No; Non nodal tumor deposits: No; Perineural invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Bevacizumab; Days to treatment start: 49 days; Days to treatment end: 212 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 49 days; Days to treatment end: 576 days (1.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 49 days; Days to treatment end: 576 days (1.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Oxaliplatin; Days to treatment start: 49 days; Days to treatment end: 212 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 476 days (1.3 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 170.

Molecular and laboratory tests
- KRAS mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 83 kg; Height: 167.6 cm; BMI: 29.5.

Family history
- Relatives with cancer history count: 1.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-NH-A6GB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 750 mg.
  Slide TCGA-NH-A6GB-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 25; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-NH-A6GB-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Samples TCGA-NH-A6GB-10A, TCGA-NH-A6GB-10B (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Weight kg at diagnosis: 83 kg; Lymph nodes examined: Yes; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: Yes; KRAS mutation found: No; BRAF gene analysis indicator: No; Colon polyps at procurement indicator: No; Mismatch rep proteins tested by IHC: No; New tumor event diagnosis indicator: No.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 476 days; disease-specific survival: no event (censored), 476 days; progression-free interval: no event (censored), 476 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-NH-A6GB-01A-11D-A36W-01): tumor purity 0.69, ploidy 2.21, whole-genome doublings 0.
